Somatic mutation profile of tumor specimen C3L-00767-01 (aliquot CPT0026430009) from CPTAC case C3L-00767, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 56.6 years (20,657 days).
Specimen C3L-00767-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3202fcdd-bcee-4af2-a9d7-152eea357be4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00767-71 (Blood Derived Normal), aliquot CPT0026490002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ed7192a-82b0-4a15-b03b-37913817c3d9

The open-access MAF lists 74 somatic variants for this specimen: 54 protein-altering or splice-affecting, 16 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 16, Intron 4, Splice Site 3, Nonsense Mutation 2, Frame Shift Del 2, In Frame Ins 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.95A>G p.D32G | Missense Mutation (SNP) | VAF 123/328 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs121913396, COSV62688001, COSV62688037, COSV62688249; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC11 | c.1433A>G p.E478G | Missense Mutation (SNP) | VAF 87/278 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1347345642; called by muse, mutect2, varscan2
- ADAMTS10 | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs572299536, COSV54357801, COSV99546818; called by muse, mutect2, varscan2
- ANKRD18A | c.898C>T p.Q300* | Nonsense Mutation (SNP) | VAF 48/156 reads (31%) | catalogued as rs1370859370; called by muse, mutect2, varscan2
- CUBN | c.4132C>T p.R1378C | Missense Mutation (SNP) | VAF 214/805 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.519); catalogued as rs1290293396, COSV64728057; called by muse, mutect2, varscan2
- DENND5B | c.3096del p.G1033Afs*15 | Frame Shift Del (DEL) | VAF 50/176 reads (28%) | catalogued as COSV60906887; called by mutect2, pindel, varscan2
- DLGAP2 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 52/149 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs1563186237; called by muse, mutect2, varscan2
- EIF1AX | c.7A>G p.K3E | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.151); catalogued as COSV65450967; called by muse, mutect2, varscan2
- ERCC6L | c.2659G>A p.D887N | Missense Mutation (SNP) | VAF 58/125 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.039); catalogued as rs1249347499; called by muse, mutect2, varscan2
- GCNA | c.649G>A p.D217N | Missense Mutation (SNP) | VAF 224/616 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV65466131; called by muse, varscan2
- GGN | c.1616G>A p.R539H | Missense Mutation (SNP) | VAF 125/379 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs200079343; called by muse, mutect2, varscan2
- GHRHR | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 107/302 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs758281879, COSV58196872; called by muse, mutect2, varscan2
- HNRNPK | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 100/239 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100698940, COSV61089457; called by muse, mutect2, varscan2
- KIF5C | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 54/124 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs745875480, COSV101276126; called by muse, mutect2, varscan2
- KNDC1 | c.2255G>A p.R752H | Missense Mutation (SNP) | VAF 61/107 reads (57%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs771852065, COSV58846483; called by muse, mutect2, varscan2
- LRRC56 | c.1157G>A p.R386K | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV104372935; called by muse, mutect2, varscan2
- MECP2 | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 89/220 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.034); catalogued as rs371234586, COSV100318468; called by muse, mutect2, varscan2
- MUC5B | c.7334C>A p.T2445K | Missense Mutation (SNP) | VAF 173/450 reads (38%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.544); catalogued as rs756364374, COSV101500091; called by muse, mutect2, varscan2
- NOA1 | c.1930C>T p.R644* | Nonsense Mutation (SNP) | VAF 28/220 reads (13%) | catalogued as rs774862770, COSV99950426; called by muse, mutect2, varscan2
- NRXN1 | c.1442C>A p.P481Q | Missense Mutation (SNP) | VAF 18/338 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100453951; called by muse, mutect2
- OR6C1 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.436); catalogued as rs764018691; called by muse, mutect2, varscan2
- PC | c.2024G>A p.R675H | Missense Mutation (SNP) | VAF 123/341 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs375528540; called by muse, varscan2
- SGMS1 | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 50/186 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV100693743; called by muse, mutect2, varscan2
- STARD8 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 63/173 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs757767955, COSV52926613; called by muse, mutect2, varscan2
- TADA2A | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 78/199 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.291); catalogued as rs746746027; called by muse, mutect2, varscan2
- TRAF3IP2 | c.1228+1G>C p.X410_splice | Splice Site (SNP) | VAF 54/142 reads (38%) | catalogued as rs375800644, COSV100389662, COSV60676165; called by muse, mutect2, varscan2
- TRIM11 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 69/155 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as rs370800532, COSV99488278; called by muse, mutect2, varscan2
- VIT | c.1595C>T p.T532M (on ENST00000389975 / NM_001177969.1; = p.T547M on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/178 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200951052, COSV64899172, COSV64900385; called by muse, mutect2, varscan2
- ABCB4 | c.2196C>A p.F732L | Missense Mutation (SNP) | VAF 126/364 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CACNA1E | c.2542G>C p.E848Q | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CASKIN2 | c.1574C>T p.P525L | Missense Mutation (SNP) | VAF 48/161 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCNJL | c.1033C>A p.Q345K | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.072); called by muse, varscan2
- CDH7 | c.857C>A p.A286D | Missense Mutation (SNP) | VAF 55/118 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- CENPE | c.95A>G p.K32R | Missense Mutation (SNP) | VAF 89/191 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- DTX1 | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IWS1 | c.2387C>T p.T796I | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- MTMR12 | c.182A>T p.Y61F | Missense Mutation (SNP) | VAF 62/173 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- NLK | c.625A>T p.I209F | Missense Mutation (SNP) | VAF 70/206 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.05); called by muse, varscan2
- NRROS | c.1348G>T p.V450L | Missense Mutation (SNP) | VAF 68/181 reads (38%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR13C3 | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 94/285 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- OR2M3 | c.635C>A p.A212E | Missense Mutation (SNP) | VAF 128/356 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- PCDHB5 | c.1540G>T p.A514S | Missense Mutation (SNP) | VAF 244/720 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PEX5L | c.726+2T>A p.X242_splice | Splice Site (SNP) | VAF 68/158 reads (43%) | called by muse, mutect2, varscan2
- PFKL | c.530G>A p.G177D | Missense Mutation (SNP) | VAF 89/213 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIK3R1 | c.1378_1386dup p.S460_E462dup (on ENST00000521381 / NM_181523.3; = p.S190_E192dup on NM_181504.4) | In Frame Ins (INS) | VAF 34/138 reads (25%) | called by mutect2, varscan2
- PPDPFL | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- PTEN | c.962_965del p.T321Kfs*22 | Frame Shift Del (DEL) | VAF 81/242 reads (33%) | called by pindel, varscan2
- RBSN | c.511A>G p.S171G | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- RNF43 | c.265dup p.Y89Lfs*7 | Frame Shift Ins (INS) | VAF 13/38 reads (34%) | called by mutect2, pindel, varscan2
- RPS3 | c.681G>C p.K227N | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- SRRM3 | c.485G>T p.S162I | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRAM1L1 | c.335C>T p.T112I | Missense Mutation (SNP) | VAF 67/180 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- TTN | c.22147+1G>C p.X7383_splice (on ENST00000591111; = p.X6456_splice on NM_133378.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 13/42 reads (31%) | called by muse, mutect2, varscan2
- USP26 | c.389C>A p.T130N | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- ADRA1B | c.1284G>A p.P428= | Silent (SNP) | VAF 14/45 reads (31%) | called by muse, mutect2, varscan2
- ATF7IP2 | c.945A>G p.T315= | Silent (SNP) | VAF 101/271 reads (37%) | called by muse, mutect2, varscan2
- ATP8A1 | c.1755G>A p.T585= | Silent (SNP) | VAF 39/134 reads (29%) | catalogued as rs561646938, COSV52532544, COSV52535311; called by muse, mutect2, varscan2
- COL5A2 | c.3912C>T p.S1304= | Silent (SNP) | VAF 137/329 reads (42%) | catalogued as rs571598585; called by muse, mutect2, varscan2
- DLK1 | c.549C>T p.G183= | Silent (SNP) | VAF 77/182 reads (42%) | catalogued as rs753924809; called by muse, mutect2, varscan2
- EPB41L1 | c.2247G>A p.T749= | Silent (SNP) | VAF 79/254 reads (31%) | catalogued as rs144598363; called by muse, mutect2, varscan2
- IMMT | c.2202G>A p.T734= | Silent (SNP) | VAF 108/295 reads (37%) | catalogued as rs370590382; called by muse, mutect2, varscan2
- ITGAX | c.1419C>T p.T473= | Silent (SNP) | VAF 43/156 reads (28%) | catalogued as rs998010127; called by muse, mutect2, varscan2
- OR8H1 | c.294C>T p.A98= | Silent (SNP) | VAF 59/176 reads (34%) | called by muse, mutect2, varscan2
- PCDHGA3 | c.597C>T p.A199= | Silent (SNP) | VAF 60/145 reads (41%) | called by muse, mutect2, varscan2
- PIK3C2G | c.4293C>A p.P1431= (on ENST00000676171; = p.P1390= on NM_004570.5) | Silent (SNP) | VAF 66/141 reads (47%) | called by muse, mutect2, varscan2
- PPARG | c.1020C>T p.N340= (on ENST00000287820 / NM_015869.5; = p.N310= on NM_005037.7) | Silent (SNP) | VAF 65/213 reads (31%) | catalogued as rs748471505, CD066392; called by muse, mutect2, varscan2
- SHROOM2 | c.618C>T p.R206= | Silent (SNP) | VAF 108/349 reads (31%) | catalogued as rs764456682, COSV101098018; called by muse, mutect2, varscan2
- TTC19 | c.723C>T p.D241= | Silent (SNP) | VAF 34/359 reads (9%) | catalogued as rs149658292; ClinVar: likely benign; called by muse, mutect2
- WDFY4 | c.855C>T p.S285= | Silent (SNP) | VAF 88/309 reads (28%) | catalogued as rs1046307692; called by muse, mutect2, varscan2
- ZNF33B | c.1497T>C p.C499= | Silent (SNP) | VAF 30/472 reads (6%) | called by muse, mutect2
- CTBP2 | c.58+11964G>A | Intron (SNP) | VAF 37/134 reads (28%) | catalogued as rs748825639; called by muse, mutect2, varscan2
- PDHB | c.205-11C>G | Intron (SNP) | VAF 40/508 reads (8%) | called by muse, mutect2
- SNED1 | c.3817+149C>T | Intron (SNP) | VAF 47/134 reads (35%) | catalogued as rs373058294; called by muse, mutect2, varscan2
- TTLL3 | c.2125+18C>T | Intron (SNP) | VAF 23/211 reads (11%) | called by muse, mutect2
